Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PC, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PC-01A (Primary Tumor).

ICD-0.3
Adenocarcinoma, signet ring
cell 8490/3
Site Gastric antrum C16.3
03/7/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Antrum)

Product of gastrectomy:

Adenocarcinoma:

Histological pattern observed:

Mucosecretor mucocellular cell in "signet ring"

Histological grade:

III - poorly differentiated.

Lauren's classification: diffuse type

Measure the longest axis of the tumor: 3.5 cm

Ulceration: present

Involvement of: serous

Type of tumor invasion: spiculated

Inflammatory reaction: mild

Proximal and distal margins: absence of neoplastic involvement.

Neural infiltration: not detected

Lymphatic vascular invasion: not detected

Blood vascular invasion: not detected

Small omentum: absence of neoplastic involvement.

Lymph nodes of greater curvature:

Absence of neoplasia: (0/5)

Lymph nodes of lesser curvature:

Adenocarcinoma metastasis with capsular transposition (1/2)

Subpyloric lymph node:

Absence of neoplasia: (0/1)

Celiac trunk lymph node:

Adenocarcinoma metastasis with capsular transposition (1/1)

Right paracardiac lymph nodes:

Absence of neoplasia: (0/5)

Lymph node of hepatic artery:

Absence of neoplasia: (0/1)

ICDPA Discrepancy		
Primary Malignancy History		

Source: NCI Genomic Data Commons file 2f436ae8-ec6c-469a-9adf-cc80c5586170 (TCGA-VQ-A8PC.51D9B573-7ECD-43FB-A33F-F0E2B7DA68EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).